Surgical pathology report (de-identified scan), TCGA case TCGA-59-2363, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Roswell Park, specimen TCGA-59-2363-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S):

- A. RIGHT TUBE AND OVARY
- B. LEFT TUBE AND OVARY
- C. UTERUS
- D. CUL-DE-SAC IMPLANTS
- E. RIGHT PELVIC SIDEWALL
- F. IMPLANT
- G. RIGHT PELVIC LYMPH NODES
- H. PERI AORTIC LYMPH NODES
- I. OMENTUM
- J. APPENDIX

CLINICAL HISTORY:

[REDACTED] with ovarian mass.

PRE-OPERATIVE DIAGNOSIS:

Ovarian mass.

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA Right tube and ovary, resection: Serous papillary carcinoma.

Gross Exam B Left tube and ovary, resection: Grossly same tumor as in "A".

Gross Exam C Uterus, hysterectomy: No endometrial tumor seen. (gross examination only)

[REDACTED], call [REDACTED] (A., B) [REDACTED] (C).

GROSS DESCRIPTION:

A. RIGHT TUBE AND OVARY

Received fresh is an ovarian mass with attached fallopian tube weighing 183 grams and measuring 20 x 14.5 x 13.2 cm. The specimen is serially sectioned to reveal a tan-pink solid papillary tumor. A portion of fimbriated fallopian tube is identified (3.5 cm in length and 1.2 cm

[page 2 of 5]
[REDACTED]

in diameter) and serially sectioned to reveal a patent lumen. A portion of the specimen is submitted for tissue procurement. Representative sections are submitted as follows:

FSA1: frozen section

A2-A25: tumor sections (A25 including fallopian tube)

B. LEFT TUBE AND OVARY

Received fresh is an ovarian mass with attached fallopian tube weighing 600 grams and measuring 12.5 x 11.0 x 6.5 cm. The specimen is serially sectioned to reveal similar tumor to part A. A corpus luteum is grossly identified. A possible fallopian tube is identified and measures 1.0 cm in length and 0.3 cm in diameter. It is sectioned to reveal a pin-point lumen. A portion of the specimen is submitted for tissue procurement. Representative sections are submitted as follows:

B1: possible fallopian tube

B2-B4: corpus luteum

B5-B16: cyst wall with tumor

C. UTERUS

Received is a 147 gram uterus measuring 10 cm from fundus to ectocervix, 7.5 cm from cornu to cornu and 5 cm from anterior to posterior. The serosal surface is tan-pink and grossly unremarkable. The cervix measures 4 cm in length and 4.3 cm in diameter, and is a remarkable for a patent split-like os measuring 0.8 cm. The specimen is bivalved into anterior and posterior halves to reveal a patent endocervical canal measuring 4 cm in length. The right aspect of the cervix is remarkable for a cyst-like structure (2 x 1 cm). The triangular endocervical canal measures 5 cm in length and 2 cm in width. The tan-pink trabeculated myometrium measures 23.4 cm in greatest thickness. The endometrium measures up to 0.1 cm. No gross malignancy is identified. Representative sections are submitted as follows:

C1-C2: anterior cervix with lower uterine segment

C3-C4: posterior cervix with lower uterine segment (C4 including cyst)

C5-C7: anterior endomyometrium

C8-C9: posterior endomyometrium bisected

C10-C11: posterior endomyometrium bisected

C12: posterior endomyometrium

D. CUL-DE-SAC IMPLANTS

Labeled "cul-de-sac implants" are multiple tan-brown soft tissue fragments aggregating to (1.5 x 1.4 x 0.8 cm). Toto in D1.

E. RIGHT PELVIC SIDEWALL

Labeled "right pelvic sidewall" is a tan-pink soft tissue fragment (3.0 x 1.0 x 0.8 cm). The specimen is serially sectioned and submitted in toto in cassette E1.

F. LEFT PELVIC LYMPH NODES

Are multiple tan-pink soft tissue fragments of fibrofatty tissue aggregating to (4.0 x 2.0 x 1.0 cm). Dissection reveals 3 lymph nodes ranging from (1.0 x 0.6 x 0.5 cm to 2.0 x 1.0 x 0.8 cm). Toto as follows:

F1: 2 lymph nodes

F2: 1 lymph node serially sectioned

[REDACTED]

[page 3 of 5]
G. RIGHT PELVIC LYMPH NODES

Labeled "right pelvic lymph nodes" is a tan-pink fragment of fibrofatty tissue (3.5 x 1.5 x 0.8 cm). Dissection reveals tan-pink lymph node (2.3 x 1.0 x 0.8 cm). The specimen is serially sectioned and submitted in toto in cassette G1.

H. PERIAORTIC LYMPH NODES

Labeled "periaortic lymph nodes" are multiple fragments of fibrofatty tissue aggregating to (2.5 x 2.0 x 1.0 cm). Dissection reveals possible lymph nodes ranging from (0.6 x 0.5 x 0.5 cm to 1.0 x 1.0 x 0.8 cm). Section code:

H1: 4 possible lymph nodes

H2: 3 possible lymph nodes

I. OMENTUM

Labeled "omentum" is a tan-pink fragment of fibrofatty tissue (20.0 x 6.0 x 0.8 cm). The specimen is grossly unremarkable. The specimen is serially sectioned, and representative sections are submitted in cassettes I1 and I2.

J. APPENDIX

Labeled "appendix" is a tan-pink appendix (4.0 x 0.8 x 0.7 cm) with attached mesoappendix (3.0 x 0.5 cm). The serosa is tan-pink and grossly unremarkable. The specimen is serially sectioned to reveal a patent lumen ranging from (0.5 cm to 0.8 cm) filled with brown fecal material. The wall thickness measures 0.1 cm. The tip is longitudinally sectioned, and the specimen is submitted entirely in cassette J1 and J2 as follows:

J1: Tip bivalved

J2: Remainder of specimen

DIAGNOSIS:

A. OVARY AND FALLOPIAN TUBE, RIGHT; ADNEXECTOMY:

- SEROUS ADENOCARCINOMA, GRADE 3 (20 CM)
- BENIGN FALLOPIAN TUBE

B. OVARY AND FALLOPIAN TUBE, LEFT; ADNEXECTOMY:

- SEROUS ADENOCARCINOMA, GRADE 3 (12.5 CM)
- BENIGN FALLOPIAN TUBE
-

C. UTERUS, HYSTERECTOMY:

- PROLIFERATIVE ENDOMETRIUM, ADENOMYOSIS, UNREMARKABLE CERVICAL MUCOSA AND FOCAL SEROSAL IMPLANTS OF SEROUS ADENOCARCINOMA.

D. PERITONEUM, CUL-DE-SAC IMPLANTS; BIOPSY:

- SEROUS ADENOCARCINOMA INVOLVING PERITONEUM

E. PERITONEUM, RIGHT PELVIC SIDEWALL IMPLANT; BIOPSY:

- SEROUS ADENOCARCINOMA INVOLVING PERITONEUM
-

[page 4 of 5]
[REDACTED]

F. LYMPH NODES, LEFT PELVIC; DISSECTION:

- THREE BENIGN LYMPH NODES (0/3)

G. LYMPH NODES, RIGHT PELVIC; DISSECTION:

- SIX BENIGN LYMPH NODES (0/6)

H. LYMPH NODES, PERIAORTIC; DISSECTION:

- SIX BENIGN LYMPH NODES (0/6)

I. OMENTUM, RESECTION:

- MICROSCOPIC SUPERFICIAL IMPLANTS OF SEROUS TUMOR.

J. APPENDIX; RESECTION:

- UNREMARKABLE APPENDICEAL MUCOSA

SYNOPTIC REPORT - OVARY

Specimens Involved

Specimens: A: RIGHT TUBE AND OVARY

B: LEFT TUBE AND OVARY

C: UTERUS

D: CUL-DE-SAC IMPLANTS

E: RIGHT PELVIC SIDEWALL IMPLANT

F: LEFT PELVIC LYMPH NODES

G: RIGHT PELVIC LYMPH NODES

H: PERI AORTIC LYMPH NODES

I: OMENTUM

Specimen Type: [REDACTED]

Primary tumor site and size: Right Side

Involved

Largest Dimension: 20cm

Left Side

Involved

Largest Dimension: 12.5cm

Specimen integrity: Intact

Gross surface involvement: Yes

Cut surface: Cystic and Solid; Cystic 85% Solid 15%

Gross necrosis: Yes

WHO CLASSIFICATION

Serous tumors

Adenocarcinoma 8441/3

TUMOR GRADING

Architecture pattern: 2 (Papillary)

Cytologic atypia: 3

[REDACTED]

[page 5 of 5]
Mitotic grade: 3 (>25)

Silverberg grading system: 3 (Score 8 or 9)

Summary of organs/tissues microscopically involved: Both ovaries
Omentum
Peritoneum
Uterine serosa

Venous/lymphatic invasion: Absent

Implants: N/A

Lymph node dissection: Yes Right pelvic 0 / 6 Left pelvic 0 / 3 Paraaortic 0 / 6

Peritoneal cytology if tumor limited to ovary: Positive

Cytology case #:

Additional pathologic findings: Adenomyosis

NY ESO-1: Negative

Pathologic staging (pTNM): pT 3a N 0 M x

Source: NCI Genomic Data Commons file 11b2847e-3249-42c8-b11d-a1efe03014b5 (TCGA-59-2363.9B047485-EB2B-4FC1-A22A-D96046B63BF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).